Somatic mutation profile of tumor specimen 0E27P5 from CCDI case PBCVWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E27P5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35ca3837-e400-49ff-9bb5-b18db9a1cefb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E18I4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b950237-1ea9-416b-a519-dcfaacc45d72

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 138/196 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by mutect2, varscan2
- AGPAT1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 157/469 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100421523; called by muse, mutect2, varscan2
- ARMC12 | c.998G>A p.R333H (on ENST00000373866 / NM_001286574.2; = p.R360H on NM_145028.5) | Missense Mutation (SNP) | VAF 97/577 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761266774, COSV55361183; called by muse, mutect2, varscan2
- CDH2 | c.380T>G p.L127* | Nonsense Mutation (SNP) | VAF 93/525 reads (18%) | catalogued as rs1197514285; called by muse, mutect2, varscan2
- EYS | c.6490G>T p.V2164F | Missense Mutation (SNP) | VAF 40/1252 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV65482276; called by muse, mutect2
- GRAP2 | c.769A>G p.M257V | Missense Mutation (SNP) | VAF 38/606 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.444); catalogued as COSV100703231, COSV59995476; called by muse, mutect2
- MUC5AC | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); catalogued as rs1020319640; called by muse, mutect2, varscan2
- RPS5 | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 24/409 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381721927; called by muse, mutect2
- WAC | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 295/1144 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs771242997, COSV61567319; called by muse, mutect2, varscan2
- CDH8 | c.1314G>C p.Q438H | Missense Mutation (SNP) | VAF 206/1035 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CHGA | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- FNDC10 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- HARBI1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 103/432 reads (24%) | called by muse, mutect2, varscan2
- HIVEP3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- P2RY1 | c.806T>C p.F269S | Missense Mutation (SNP) | VAF 89/457 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA8 | c.1940A>C p.Q647P | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PTPRK | c.1952G>A p.C651Y | Missense Mutation (SNP) | VAF 139/712 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TCTA | c.267G>A p.S89= | Splice Region (SNP) | VAF 83/370 reads (22%) | called by muse, mutect2, varscan2
- ADGRE3 | c.246C>T p.N82= | Silent (SNP) | VAF 90/616 reads (15%) | catalogued as rs774575203, COSV99506214; called by muse, mutect2
- ITPKA | c.156G>A p.G52= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- PCDH19 | c.2943C>A p.S981= (on ENST00000373034 / NM_001184880.2; = p.S933= on NM_020766.3) | Silent (SNP) | VAF 24/612 reads (4%) | called by muse, mutect2
- PLXNB3 | c.5214G>A p.K1738= | Silent (SNP) | VAF 50/237 reads (21%) | catalogued as rs146370406; called by muse, mutect2, varscan2
- TBC1D24 | c.907C>T p.L303= | Silent (SNP) | VAF 1873/2192 reads (85%) | called by muse, mutect2, varscan2
- BIN2 | chr12:51324556 C>T | 5'Flank (SNP) | VAF 49/223 reads (22%) | called by muse, mutect2, varscan2
